Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3LL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3LL-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Radical hysterectomy, uterus, cervix, bilateral tubes and ovaries
- 2: SP: Right pelvic lymph node
- 3: SP: Right obturator lymph node
- 4: SP: Right hypogastric lymph nodes
- 5: SP: Left obturator lymph node
- 6: SP: Left external iliac lymph node

DIAGNOSIS:

1. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES; RADICAL HYSTERECTOMY:
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED
- THE TUMOR MEASURES 3.7 X 3.4 X 3.2 CM AND INVADERS THE CERVICAL STROMA TO A DEPTH OF 19 MM IN AN AREA THAT MEASURES 20 MM IN DIMENSION
- TUMOR IS PRESENT WITHIN 1.0 MM OF THE ANTERIOR AND POSTERIOR SOFT TISSUE MARGINS
- CIN III IS IDENTIFIED
- FOCI SUSPICIOUS FOR LYMPHOVASCULAR INVASION ARE IDENTIFIED
- THE PARAMETRIA ARE NOT INVOLVED
- PERINEURAL INVASION IS NOT IDENTIFIED
- UTERINE CORPUS EXTENSION IS NOT IDENTIFIED
- VAIN III IS PRESENT AT THE ANTERIOR AND POSTERIOR VAGINAL RESECTION MARGINS
- ALL MARGINS ARE NEGATIVE FOR INVASIVE CARCINOMA
- WEAKLY PROLIFERATIVE ENDOMETRIUM AND UNREMARKABLE MYOMETRIUM
- BILATERAL OVARIES WITH STROMAL HYPERPLASIA
- BENIGN BILATERAL FALLOPIAN TUBES
- EIGHT PARAMETRIAL LYMPH NODES, NEGATIVE FOR TUMOR (0/8)

NOTE: REPRESENTATIVE SECTIONS WERE REVIEWED AT GYNECOLOGIC PATHOLOGY CONSENSUS CONFERENCE TO DETERMINE THE STATUS OF THE LEFT PARAMETRIUM. THE CONSENSUS WAS THAT THIS STRUCTURE IS NOT INVOLVED BY CARCINOMA.

2. LYMPH NODE, RIGHT PELVIC; EXCISION:
- ONE BENIGN LYMPH NODE NEGATIVE FOR TUMOR (0/1)

** Continued on next page **

105-0-3
carcinoma, squamous cell 8070/3
Site: cervix, NOS C53.9 lw
12/20/11

[page 2 of 2]
-
3. LYMPH NODE, RIGHT OBTURATOR; EXCISION:
- ONE BENIGN LYMPH NODE NEGATIVE FOR TUMOR (0/1)
4. LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- TWO BENIGN LYMPH NODES NEGATIVE FOR TUMOR (0/2)
5. LYMPH NODE, LEFT OBTURATOR; EXCISION:
- ONE BENIGN LYMPH NODE NEGATIVE FOR TUMOR (0/1)
6. LYMPH NODE, LEFT EXTERNAL ILIAC; EXCISION:
- FOUR BENIGN LYMPH NODES NEGATIVE FOR TUMOR (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file dd5e2f87-47ff-4985-8721-d77caf2a5689 (TCGA-IR-A3LL.CF29FB41-6E3C-4798-A958-37A1B1F9E7AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).